CCDI case PBCGNN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c75e1bc3-dd15-406e-a797-e82d211cbe16

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.9 years (2,150 days).

Biospecimens (3 samples)
- Sample 0DRKKD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRKKW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
